Somatic mutation profile of tumor specimen TARGET-40-NAAGJX-01A (aliquot TARGET-40-NAAGJX-01A-01D) from TARGET case TARGET-40-NAAGJX, project TARGET-OS (Osteosarcoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Osteosarcoma, NOS; Tissue or organ of origin: Long bones of upper limb, scapula and associated joints; Age at diagnosis: 10.1 years (3,700 days).
Specimen TARGET-40-NAAGJX-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4bae2dec-717a-402b-8848-f72d01776f96.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-40-NAAGJX-10A (Blood Derived Normal), aliquot TARGET-40-NAAGJX-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/10100688-e11c-4576-b59d-2278769ddf0a

The open-access MAF lists 11 somatic variants for this specimen: 10 protein-altering or splice-affecting, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 9, Intron 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CEP63 | c.1621A>T p.I541F | Missense Mutation (SNP) | VAF 14/20 reads (70%) | SIFT deleterious (0.05); PolyPhen benign (0.172); catalogued as COSV59680205; called by mutect2, varscan2
- ACACB | c.7012C>T p.Q2338* | Nonsense Mutation (SNP) | VAF 30/95 reads (32%) | called by muse, mutect2, varscan2
- AHNAK2 | c.13073A>G p.Q4358R | Missense Mutation (SNP) | VAF 69/163 reads (42%) | SIFT tolerated (0.34); PolyPhen benign (0.234); called by muse, mutect2, varscan2
- ALMS1 | c.6959A>C p.Q2320P | Missense Mutation (SNP) | VAF 32/75 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.786); called by muse, mutect2, varscan2
- CARD14 | c.2668G>A p.A890T | Missense Mutation (SNP) | VAF 22/55 reads (40%) | SIFT tolerated (0.1); PolyPhen benign (0.272); called by muse, mutect2, varscan2
- CELSR1 | c.753G>T p.Q251H | Missense Mutation (SNP) | VAF 20/57 reads (35%) | SIFT deleterious (0.05); PolyPhen benign (0.104); called by muse, mutect2, varscan2
- ERC1 | c.2447G>C p.R816P (on ENST00000360905 / NM_178040.4; = p.R788P on NM_178039.4) | Missense Mutation (SNP) | VAF 23/83 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- LRRTM4 | c.639G>T p.E213D | Missense Mutation (SNP) | VAF 24/65 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MAML3 | c.3019A>T p.S1007C | Missense Mutation (SNP) | VAF 61/251 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.43); called by muse, mutect2, varscan2
- UBR1 | c.2108A>G p.D703G | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); called by muse, mutect2, varscan2
- IGFN1 | c.1242-1249A>G | Intron (SNP) | VAF 29/128 reads (23%) | called by muse, mutect2, varscan2
